MMRF case MMRF_1360 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/db3f8b94-ddec-44c2-a20c-523901e5adf7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.9 years (23,709 days); ISS stage: II; Days to last known disease status: 1,414 days (3.9 years); Days to last follow up: 1,414 days (3.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 207 days; Days to treatment end: 207 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14 (ECOG 1): M Protein 1.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.26 mg/dL; Beta 2 Microglobulin 2.68 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 34 g/L; Total Protein 9.9 g/dL; Glucose 5.17 mmol/L.
- Day 70 (ECOG 0): M Protein 0.8 g/dL; Hemoglobin 7.25 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 3.96 ×10⁹/L; Platelets 390 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 3.96 mmol/L.
- Day 153 (ECOG 0): M Protein 0.42 g/dL; Beta 2 Microglobulin 1.88 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 10.3 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 421 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.28 mmol/L.
- Day 236: Beta 2 Microglobulin 1.92 µg/mL; Hemoglobin 7.75 mmol/L; Leukocytes 6.6 ×10⁹/L; Platelets 86 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.58 mmol/L; Albumin 47 g/L; Total Protein 6.6 g/dL; Glucose 5.28 mmol/L.
- Day 355 (ECOG 0): Hemoglobin 7.87 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 244 ×10⁹/L.
- Day 432 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 10.3 g/L; Beta 2 Microglobulin 1.5 µg/mL; Hemoglobin 7.81 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.35 ×10⁹/L; Platelets 233 ×10⁹/L; Total Protein 6.5 g/dL.
- Day 516 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.582 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 1.86 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.79 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.06 mmol/L.
- Day 614 (ECOG 0): Hemoglobin 7.87 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.52 ×10⁹/L; Platelets 207 ×10⁹/L.
- Day 810 (ECOG 0): Hemoglobin 8 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.79 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.12 mmol/L.
- Day 881 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Beta 2 Microglobulin 1.84 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.14 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.72 mmol/L.
- Day 950 (ECOG 0): Hemoglobin 7.69 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.46 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 8.6 g/dL; Glucose 5.23 mmol/L.
- Day 1,034 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 10.8 g/L; Beta 2 Microglobulin 1.95 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.14 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.28 mmol/L.
- Day 1,160 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 1.5 µg/mL.
- Day 1,414 (ECOG 0): Hemoglobin 8.12 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 4.9 mmol/L.

Other clinical attributes
- Day -14: Weight: 83 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1360_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -14 days.
- Sample MMRF_1360_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -14 days.
